Somatic mutation profile of tumor specimen MMRF_1981_1_BM_CD138pos (aliquot MMRF_1981_1_BM_CD138pos_T1_KBS5U_L07268) from MMRF case MMRF_1981, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,187 days).
Specimen MMRF_1981_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76cd757b-25e9-482c-b04e-f12e2188acd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1981_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1981_1_PB_Whole_C3_KBS5U_L07269; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c871afb9-719e-4bff-a717-1b2af2001afa

The open-access MAF lists 168 somatic variants for this specimen: 68 protein-altering or splice-affecting, 23 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 38, Silent 23, Intron 19, 5'UTR 7, Nonsense Mutation 7, RNA 5, 5'Flank 4, 3'Flank 4, Frame Shift Del 3, Splice Region 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5907_5908del p.R1970Sfs*6 (on ENST00000358273 / NM_001042492.3; = p.R1949Sfs*6 on NM_000267.3) | Frame Shift Del (DEL) | VAF 29/106 reads (27%) | catalogued as rs863224835; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 23/45 reads (51%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.381); catalogued as COSV64418987; called by muse, mutect2, varscan2
- AKR1C4 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs782629817; called by muse, mutect2, varscan2
- AXIN1 | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV51989476, COSV51990389; called by muse, mutect2, varscan2
- BBX | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 175/709 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777321618, COSV57888347; called by muse, mutect2, varscan2
- CCDC114 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs754968402; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFAP44 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 160/654 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV99868732; called by muse, mutect2, varscan2
- CYP1A2 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 98/293 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780755833, COSV59659194; called by muse, mutect2, varscan2
- EHHADH | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 108/431 reads (25%) | catalogued as rs367840568; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT4 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV67898840, COSV67903665; called by muse, mutect2, varscan2
- FBXO15 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV54045343; called by muse, mutect2, varscan2
- IGKJ3 | c.37A>C p.K13Q | Missense Mutation (SNP) | VAF 111/111 reads (100%) | catalogued as rs1266825867; called by muse, varscan2
- ITGB6 | c.1586A>G p.Y529C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs749662298; called by muse, mutect2, varscan2
- KCNG1 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs919816936, COSV65367937; called by muse, mutect2, varscan2
- MFSD14C | n.577-1G>T | Splice Site (SNP) | VAF 23/136 reads (17%) | catalogued as COSV100923994; called by muse, mutect2, varscan2
- MRRF | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs764372197; called by muse, mutect2, varscan2
- MUC16 | c.23584G>A p.E7862K | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as rs781289985; called by muse, mutect2, varscan2
- MYO15A | c.6560G>A p.R2187H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs199913622; called by muse, mutect2, varscan2
- NCAPG2 | c.3017G>A p.G1006D | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); catalogued as rs754184868; called by muse, mutect2, varscan2
- NCLN | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs913705047; called by muse, mutect2, varscan2
- NOTCH3 | c.4838C>T p.A1613V | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1276100738; called by muse, mutect2, varscan2
- PAPSS1 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763786456; called by muse, mutect2, varscan2
- PCDHA1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV65376089; called by muse, mutect2, varscan2
- PLCB1 | c.1885A>G p.M629V | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1441152862; called by muse, mutect2, varscan2
- PPARGC1A | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 121/191 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV99337961; called by muse, mutect2, varscan2
- RASIP1 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV55802203; called by muse, mutect2, varscan2
- SYNE1 | c.453C>A p.S151R (on ENST00000367255 / NM_182961.4; = p.S158R on NM_033071.3) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55019966; called by muse, mutect2, varscan2
- THBS2 | c.1301-5G>A | Splice Region (SNP) | VAF 30/51 reads (59%) | catalogued as rs777706022; called by muse, mutect2, varscan2
- TLR5 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs201019501; called by muse, mutect2, varscan2
- WASHC5 | c.1019A>G p.Q340R | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.062); catalogued as rs779768001, COSV100573046; called by muse, mutect2, varscan2
- ZNF429 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.795); catalogued as rs1249995649; called by muse, mutect2, varscan2
- ZSCAN1 | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.835); catalogued as rs764113791, COSV56601539, COSV56605865; called by muse, mutect2, varscan2
- AFF3 | c.3523T>G p.W1175G | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ASXL3 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST1 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 49/217 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CNTNAP1 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 93/197 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- COL5A3 | c.2903G>A p.G968E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CST9L | c.92T>C p.F31S | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNHD1 | c.2148G>C p.W716C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYNC2H1 | c.10354T>A p.L3452M | Missense Mutation (SNP) | VAF 58/79 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF2AK4 | c.434T>C p.F145S | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- F2R | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HAUS4 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HEG1 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 43/147 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IDE | c.2116+7C>G | Splice Region (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- IKZF2 | c.983T>A p.L328H | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITFG2 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- LDHC | c.728A>G p.K243R | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MFSD14C | n.577G>T | Splice Region (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- OR4K2 | c.28T>A p.S10T | Missense Mutation (SNP) | VAF 64/932 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- PDE5A | c.2559G>T p.W853C | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG4B | c.3283T>A p.W1095R (on ENST00000283426; = p.W1451R on NM_052909.5) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB38 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 175/872 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RTN1 | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 112/164 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SGTA | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SOCS7 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SON | c.4205_4206del p.Y1402Cfs*62 | Frame Shift Del (DEL) | VAF 32/217 reads (15%) | called by mutect2, pindel, varscan2
- SPEG | c.932del p.P311Hfs*67 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- SVEP1 | c.2798C>A p.T933N | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TBC1D4 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPP2 | c.1067A>T p.Y356F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIP10 | c.1349C>A p.T450N (on ENST00000313244 / NM_001288962.2; = p.T394N on NM_004240.4) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TRPM3 | c.1375C>T p.Q459* (on ENST00000357533 / NM_001366142.2; = p.Q304* on NM_020952.6) | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- USF3 | c.3121_3123dup p.S1042dup | In Frame Ins (INS) | VAF 32/118 reads (27%) | called by mutect2, pindel, varscan2
- ZNF367 | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF543 | c.721C>G p.H241D | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- ZNF780A | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- CASP5 | c.849G>A p.P283= | Silent (SNP) | VAF 74/402 reads (18%) | catalogued as rs113183781, COSV99507971; called by muse, mutect2, varscan2
- CDC14C | c.1201C>T p.L401= (on ENST00000428251; = p.L294= on NM_152627.3) | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs778575448; called by muse, mutect2, varscan2
- DIO2 | c.144C>T p.R48= | Silent (SNP) | VAF 97/97 reads (100%) | catalogued as rs755131907; called by muse, mutect2, varscan2
- DSCAM | c.4989C>A p.P1663= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- FGD6 | c.162A>C p.P54= | Silent (SNP) | VAF 76/154 reads (49%) | catalogued as rs1417551337; called by muse, mutect2, varscan2
- FITM1 | c.204G>C p.P68= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV52823625; called by muse, mutect2, varscan2
- IGHV2-70 | c.54A>G p.L18= | Silent (SNP) | VAF 88/88 reads (100%) | catalogued as rs187704106; called by muse, mutect2, varscan2
- KIF13A | c.4743C>G p.V1581= | Silent (SNP) | VAF 67/163 reads (41%) | called by muse, mutect2, varscan2
- MAP1A | c.2250C>T p.I750= | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as rs267604221; called by muse, mutect2, varscan2
- MUC6 | c.1197G>A p.L399= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as rs1391626642; called by muse, mutect2, varscan2
- MYO9A | c.4119C>A p.A1373= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- NME7 | c.768G>A p.K256= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- OAF | c.309C>T p.V103= | Silent (SNP) | VAF 66/320 reads (21%) | catalogued as rs1306625219; called by muse, mutect2, varscan2
- PLEKHH1 | c.3894C>T p.S1298= | Silent (SNP) | VAF 16/68 reads (24%) | called by muse, mutect2, varscan2
- PRKDC | c.3780C>T p.L1260= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as rs766735361; called by muse, mutect2, varscan2
- SIGIRR | c.60G>T p.L20= | Silent (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- TAS2R10 | c.444G>A p.A148= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs761166638, COSV53700673, COSV99555452; called by muse, mutect2, varscan2
- TBC1D14 | c.201G>A p.G67= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV68984847; called by muse, mutect2, varscan2
- UCHL3 | c.604T>C p.L202= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- ZAR1 | c.720C>T p.D240= | Silent (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- ZNF43 | c.2289A>G p.K763= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- ZNF516 | c.1821G>A p.P607= | Silent (SNP) | VAF 75/93 reads (81%) | catalogued as rs533522002, COSV71587636; called by muse, mutect2, varscan2
- ZNF701 | c.663C>T p.H221= (on ENST00000301093; = p.H155= on NM_018260.3) | Silent (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- ABAT | c.*2999A>T | 3'UTR (SNP) | VAF 10/40 reads (25%) | catalogued as COSV51624909; called by muse, mutect2, varscan2
- ABCB6 | c.1387-70G>T | Intron (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- AC135782.1 | n.389C>T | RNA (SNP) | VAF 26/50 reads (52%) | catalogued as rs937312078; called by muse, mutect2, varscan2
- ADAM8 | c.-14T>A | 5'UTR (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ADRA1D | c.*706A>G | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- AL137060.9 | chr13:50043939 C>T | 5'Flank (SNP) | VAF 73/182 reads (40%) | called by muse, mutect2, varscan2
- AUTS2 | c.1933-53T>C | Intron (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2
- BCAT1 | c.*1714A>C | 3'UTR (SNP) | VAF 44/90 reads (49%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021504 A>C | 5'Flank (SNP) | VAF 29/60 reads (48%) | catalogued as rs1015499065; called by muse, mutect2, varscan2
- BNIP2 | c.*2004C>T | 3'UTR (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- CALML3-AS1 | n.2987A>G | RNA (SNP) | VAF 14/21 reads (67%) | called by muse, mutect2
- CCDC162P | n.4153G>C | RNA (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- CCR4 | c.*427G>A | 3'UTR (SNP) | VAF 39/144 reads (27%) | catalogued as rs532415931; called by muse, mutect2, varscan2
- CFAP69 | c.*768G>T | 3'UTR (SNP) | VAF 39/84 reads (46%) | catalogued as COSV60188134; called by muse, mutect2, varscan2
- CHID1 | c.960-35G>C | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- CHM | c.315-5299C>G | Intron (SNP) | VAF 35/36 reads (97%) | called by muse, mutect2, varscan2
- CHODL | c.-204G>A | 5'UTR (SNP) | VAF 36/130 reads (28%) | called by muse, mutect2, varscan2
- CSNK1G3 | chr5:123616302 T>C | 3'Flank (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- CYP39A1 | c.*397dup | 3'UTR (INS) | VAF 4/42 reads (10%) | called by mutect2, pindel
- DAGLA | c.*1413A>C | 3'UTR (SNP) | VAF 26/146 reads (18%) | called by muse, mutect2, varscan2
- DLAT | c.1814+106G>A | Intron (SNP) | VAF 67/109 reads (61%) | catalogued as rs587637247, COSV54771455; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.*830del | 3'UTR (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- EMC1 | c.*2795T>A | 3'UTR (SNP) | VAF 27/56 reads (48%) | catalogued as rs1452500478; called by muse, mutect2, varscan2
- EOGT | c.*1358A>G | 3'UTR (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- ESRRB | c.1296+514C>T | Intron (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- FANCD2 | c.695+870dup | Intron (INS) | VAF 36/172 reads (21%) | catalogued as rs762172462; called by mutect2, varscan2
- FOXRED1 | c.-25C>T | 5'UTR (SNP) | VAF 21/151 reads (14%) | catalogued as rs1240917137, COSV99703071; called by muse, mutect2, varscan2
- GPR155 | chr2:174433811 del TA | 3'Flank (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel
- GRK2 | c.*168C>T | 3'UTR (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- GRM7 | c.*598T>C | 3'UTR (SNP) | VAF 83/118 reads (70%) | called by mutect2, varscan2
- GVINP1 | n.4236A>C | RNA (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
- H2AZ2 | chr7:44828248 C>A | 3'Flank (SNP) | VAF 26/95 reads (27%) | catalogued as rs576727844; called by muse, mutect2, varscan2
- ISX | c.*763G>T | 3'UTR (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- JADE1 | c.1503+1479_1503+1480del | Intron (DEL) | VAF 32/117 reads (27%) | called by pindel, varscan2
- KIAA1958 | c.*7508A>G | 3'UTR (SNP) | VAF 8/42 reads (19%) | catalogued as rs1271511670; called by muse, mutect2
- LTBP3 | c.1721-344T>G | Intron (SNP) | VAF 266/452 reads (59%) | called by muse, mutect2, varscan2
- MAP11 | c.-117C>T | 5'UTR (SNP) | VAF 3/34 reads (9%) | catalogued as rs1331365994; called by muse, mutect2
- MAPK8 | c.*1158G>A | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- MLIP | c.1114-13055T>C | Intron (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2
- MSH6 | c.-33C>T | 5'UTR (SNP) | VAF 14/119 reads (12%) | catalogued as rs1306282819; called by muse, mutect2
- MYO10 | c.-316C>G | 5'UTR (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2
- NAT1 | c.*216_*218del | 3'UTR (DEL) | VAF 4/30 reads (13%) | catalogued as rs869146186; called by mutect2, pindel
- NEGR1 | c.*2583T>C | 3'UTR (SNP) | VAF 32/74 reads (43%) | called by muse, mutect2, varscan2
- NFRKB | c.-21-469T>G | Intron (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2
- NLGN1 | c.*1836del | 3'UTR (DEL) | VAF 16/100 reads (16%) | catalogued as rs886951308; called by mutect2, varscan2
- NRXN1 | c.3245-920T>C | Intron (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- OBSCN | chr1:228203761 G>A | 5'Flank (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- OR10G3 | c.*117G>A | 3'UTR (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2
- PBXIP1 | c.*192C>A | 3'UTR (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2
- PCDHGA3 | c.2425-67640C>A | Intron (SNP) | VAF 44/259 reads (17%) | called by muse, mutect2, varscan2
- PDE10A | c.*3799T>G | 3'UTR (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- PTGS2 | c.*1980T>C | 3'UTR (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- RAB11B | c.*61C>G | 3'UTR (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100033037; called by muse, mutect2, varscan2
- RABGAP1 | c.*786_*789del | 3'UTR (DEL) | VAF 10/33 reads (30%) | catalogued as rs567921044; called by pindel, varscan2
- RNA5SP283 | chr9:62801714 C>A | 3'Flank (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- RNF144A | c.*934C>A | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- RP9P | n.867G>A | RNA (SNP) | VAF 102/325 reads (31%) | called by muse, mutect2, varscan2
- SOCS2 | c.*961A>G | 3'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- STX6 | chr1:181022913 C>T | 5'Flank (SNP) | VAF 8/10 reads (80%) | called by muse, mutect2, varscan2
- SUGCT | c.1090-65325C>T | Intron (SNP) | VAF 23/58 reads (40%) | catalogued as rs769411959; called by muse, mutect2, varscan2
- SYBU | c.*471C>G | 3'UTR (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- SYNRG | c.*4013A>T | 3'UTR (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- SYT7 | c.215+4819G>A | Intron (SNP) | VAF 19/51 reads (37%) | catalogued as rs1308387247; called by muse, mutect2, varscan2
- TECTB | c.*1032G>A | 3'UTR (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- TFEC | c.*3116A>T | 3'UTR (SNP) | VAF 48/85 reads (56%) | called by muse, mutect2, varscan2
- TM9SF3 | c.298+65C>T | Intron (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- TMEM208 | c.-73C>T | 5'UTR (SNP) | VAF 61/118 reads (52%) | catalogued as rs989587321; called by muse, mutect2, varscan2
- TMEM9B | c.105+105T>A | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, varscan2
- TMEM9B | c.105+34C>T | Intron (SNP) | VAF 24/60 reads (40%) | catalogued as rs1209792809; called by muse, varscan2
- TNFAIP8 | c.*892T>C | 3'UTR (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- TRIM9 | c.*1143C>T | 3'UTR (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- TWSG1 | c.*421T>C | 3'UTR (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- UMPS | c.*603G>T | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, varscan2
- YAP1 | c.*2781C>T | 3'UTR (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- YWHAZ | c.582+20del | Intron (DEL) | VAF 29/61 reads (48%) | catalogued as rs1315818893; called by mutect2, pindel, varscan2
- ZC3H12C | c.*777G>C | 3'UTR (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- ZC3H14 | c.*3395G>T | 3'UTR (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
